CCDI case PBBZTL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/2a561600-c00b-4a50-82e1-dff44113499d

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 14.5 years (5,312 days).

Biospecimens (3 samples)
- Sample 0DLV2Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLV3N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DN1BL: Tissue type: Tumor; Specimen type: Solid Tissue.
